Somatic mutation profile of tumor specimen TCGA-AX-A3G3-01A (aliquot TCGA-AX-A3G3-01A-11D-A20S-09) from TCGA case TCGA-AX-A3G3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 58.3 years (21,308 days).
Specimen TCGA-AX-A3G3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55356761-a61d-4fdb-977c-20f201207d15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A3G3-10A (Blood Derived Normal), aliquot TCGA-AX-A3G3-10A-01D-A20S-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afa34f4a-599f-49c0-96b5-96108c6732b6

The open-access MAF lists 148 somatic variants for this specimen: 111 protein-altering or splice-affecting, 33 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 33, Nonsense Mutation 7, Frame Shift Del 2, Intron 2, In Frame Del 2, 3'UTR 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.734G>C p.G245A | Missense Mutation (SNP) | VAF 30/41 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.4940A>G p.H1647R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV101330175; called by muse, mutect2, varscan2
- ABCC1 | c.3692G>A p.G1231D | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100580329; called by muse, mutect2, varscan2
- ADAM23 | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100008799; called by muse, mutect2, varscan2
- AMDHD1 | c.877G>T p.V293F | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV99900521; called by muse, mutect2, varscan2
- ANKRD24 | c.1385T>C p.V462A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as rs1462826119, COSV99518135; called by mutect2, varscan2
- ANKS1A | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100832818; called by muse, mutect2
- AP3B1 | c.1824G>C p.E608D | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV99672447; called by muse, mutect2, varscan2
- APOBEC2 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV55142837, COSV99775439; called by muse, mutect2, varscan2
- ARL5B | c.112A>G p.M38V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV101040399; called by muse, mutect2, varscan2
- ARRB1 | c.88C>T p.H30Y | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100758198; called by muse, mutect2, varscan2
- ATP2B3 | c.903G>C p.K301N | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV99685810; called by muse, mutect2
- BCLAF3 | c.299C>G p.S100W | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV100503401, COSV61413206; called by muse, mutect2, varscan2
- BICD1 | c.1303A>G p.K435E | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV99862986; called by muse, mutect2, varscan2
- C4BPA | c.461G>T p.C154F | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100891283; called by muse, mutect2, varscan2
- CCDC158 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV101187364; called by muse, mutect2, varscan2
- CEP350 | c.7351C>A p.H2451N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100855218; called by muse, mutect2, varscan2
- CEP76 | c.191A>G p.D64G | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV100042972; called by muse, mutect2, varscan2
- CFAP65 | c.4149G>T p.T1383= | Splice Region (SNP) | VAF 6/22 reads (27%) | catalogued as COSV58562516, COSV58566832; called by muse, mutect2, varscan2
- CLEC2B | c.368G>T p.C123F | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV57310779, COSV99947069; called by muse, mutect2, varscan2
- CLEC4D | c.520C>G p.P174A | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as rs768905111, COSV100223165; called by muse, mutect2, varscan2
- CSMD3 | c.9027G>T p.E3009D (on ENST00000297405 / NM_001363185.1; = p.E2840D on NM_052900.3) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52341990; called by muse, mutect2, varscan2
- CYP2A13 | c.607C>A p.R203S | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as rs745929748, COSV100387017, COSV57838994; called by muse, mutect2, varscan2
- CYP4Z1 | c.1082A>C p.Q361P | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV100497919; called by muse, mutect2, varscan2
- DDR2 | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV100906841; called by mutect2, varscan2
- DICER1 | c.2296C>A p.Q766K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.718); catalogued as COSV100602547; called by muse, mutect2, varscan2
- DMRT2 | c.1411T>A p.F471I | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.588); catalogued as COSV99426235; called by muse, mutect2
- DOP1A | c.2155T>A p.S719T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99382911; called by muse, mutect2, varscan2
- DYSF | c.970T>A p.S324T | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.314); catalogued as COSV99250355; called by muse, mutect2, varscan2
- FAT4 | c.3288C>G p.N1096K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101272782; called by muse, mutect2, varscan2
- FBXO6 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs748428154, COSV99335746; called by muse, mutect2, varscan2
- FLNB | c.5360G>C p.R1787T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as rs1490706102, COSV99914806; called by muse, mutect2, varscan2
- GLI3 | c.4003C>A p.P1335T | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.023); catalogued as COSV101230039, COSV67891876; called by muse, mutect2, varscan2
- GRIK4 | c.431C>G p.T144S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.604); catalogued as COSV101483759; called by muse, mutect2
- HAUS8 | c.20G>C p.R7P | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV53727837; called by muse, mutect2, varscan2
- HDAC9 | c.1149A>T p.L383F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV101287500; called by mutect2, varscan2
- HIVEP3 | c.3461A>G p.H1154R | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); catalogued as COSV99913971; called by muse, mutect2, varscan2
- HSPG2 | c.12781A>T p.S4261C | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100760931; called by muse, mutect2, varscan2
- INO80 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100732066; called by muse, mutect2
- ITGAD | c.472T>G p.S158A | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101210581, COSV66757912; called by muse, mutect2, varscan2
- ITGAD | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101210582; called by muse, mutect2, varscan2
- KMT2E | c.4469C>A p.T1490K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV99996980; called by muse, mutect2
- KRTAP26-1 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.592); catalogued as COSV100860482; called by muse, mutect2, varscan2
- KY | c.332C>A p.A111D | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs924859054, COSV101415036; called by muse, mutect2
- LHFPL5 | c.464G>C p.S155T | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.182); catalogued as COSV100799018; called by muse, mutect2
- LIPI | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746391309, COSV100754010; called by muse, mutect2, varscan2
- LMO7 | c.920C>G p.S307C (on ENST00000357063; = p.S322C on NM_005358.5) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as COSV100413841; called by muse, mutect2
- LRRC25 | c.556C>A p.L186M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100170613; called by muse, mutect2, varscan2
- MAN1A2 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV62978589; called by muse, mutect2, varscan2
- MAP3K1 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101267108; called by muse, mutect2, varscan2
- MET | c.6G>C p.K2N | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV100577370, COSV59261682; called by muse, mutect2, varscan2
- MICU2 | c.995C>A p.A332D | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV101212491; called by muse, mutect2, varscan2
- MKI67 | c.7700C>T p.S2567L | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs1045524520, COSV100896976; called by muse, mutect2
- MUC17 | c.5455C>G p.L1819V | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV100075011; called by muse, mutect2
- MYOM1 | c.2065G>C p.E689Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV99868364; called by muse, mutect2, varscan2
- NFATC3 | c.1259T>C p.L420P | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1218851163, COSV100285711; called by muse, mutect2, varscan2
- NMNAT2 | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as COSV54267792, COSV54269018, COSV99680370; called by muse, mutect2
- NOL6 | c.2626C>G p.L876V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV99955197; called by muse, mutect2, varscan2
- NR3C1 | c.1850G>C p.S617T | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99196696; called by muse, mutect2
- NRAP | c.3598A>G p.S1200G (on ENST00000359988 / NM_001322945.2; = p.S1165G on NM_006175.4) | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100748607; called by muse, mutect2
- NUP205 | c.162C>G p.F54L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV53658929, COSV99606496; called by muse, mutect2
- NUP214 | c.3079A>C p.S1027R | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs766317730, COSV100845388; called by muse, mutect2, varscan2
- OR2J2 | c.70C>G p.L24V | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as rs759770156, COSV101013465; called by muse, mutect2, varscan2
- OTOGL | c.2792T>G p.V931G (on ENST00000547103; = p.V922G on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV101509502; called by muse, mutect2, varscan2
- P2RY14 | c.602T>A p.L201* | Nonsense Mutation (SNP) | VAF 13/75 reads (17%) | catalogued as COSV99854646; called by muse, mutect2, varscan2
- PARD3B | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs199890873, COSV62507799; called by muse, mutect2
- PARP2 | c.1035G>C p.K345N | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.576); catalogued as COSV51641728, COSV99163058; called by muse, mutect2, varscan2
- PBOV1 | c.100A>G p.R34G | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); catalogued as COSV99294672; called by muse, mutect2, varscan2
- PEG3 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.222); catalogued as rs754473044, COSV55631785; called by muse, mutect2, varscan2
- PIM1 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.035); catalogued as rs531611030, COSV100998770; called by muse, mutect2, varscan2
- PKHD1L1 | c.2541A>T p.R847S | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV101006810; called by muse, mutect2
- PLAGL2 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV99867563; called by muse, mutect2, varscan2
- PLXNA1 | c.5657A>G p.E1886G | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV99304074; called by muse, mutect2, varscan2
- POLG2 | c.689G>C p.S230T | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV101604446; called by muse, mutect2, varscan2
- POLR2F | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 17/22 reads (77%) | catalogued as COSV68410728; called by muse, mutect2, varscan2
- PTPN14 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100872922; called by muse, mutect2, varscan2
- PTPN22 | c.2116T>C p.F706L (on ENST00000359785 / NM_001193431.2; = p.F651L on NM_012411.5) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV100703959; called by muse, mutect2, varscan2
- PZP | c.2122G>C p.V708L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0.013); catalogued as COSV99739416; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100365776; called by muse, mutect2, varscan2
- REG3G | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as COSV99709703; called by muse, mutect2, varscan2
- RPRD2 | c.3940G>A p.E1314K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV100955366; called by muse, mutect2, varscan2
- SDK1 | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.362); catalogued as COSV101269839; called by mutect2, varscan2
- SIRT4 | c.782C>A p.S261* | Nonsense Mutation (SNP) | VAF 8/165 reads (5%) | catalogued as COSV99177478; called by muse, mutect2
- SLPI | c.164G>A p.W55* | Nonsense Mutation (SNP) | VAF 9/113 reads (8%) | catalogued as COSV100619797; called by muse, mutect2
- STARD8 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.121); catalogued as COSV99367628; called by muse, mutect2, varscan2
- STYXL2 | c.89T>A p.L30H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs1382340943, COSV99609874; called by muse, mutect2, varscan2
- TF | c.1844G>T p.C615F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as COSV99396395; called by muse, mutect2, varscan2
- TMEM63B | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1372358986, COSV99442088; called by muse, mutect2, varscan2
- TNIK | c.1900G>T p.E634* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | catalogued as COSV99459535; called by muse, mutect2
- TRAPPC8 | c.2469A>T p.R823S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV99351956; called by muse, mutect2, varscan2
- TTN | c.11610T>A p.S3870R (on ENST00000591111; = p.S3824R on NM_003319.4) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100629453; called by mutect2, varscan2
- TUT7 | c.3908C>G p.A1303G | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV99463641; called by muse, mutect2, varscan2
- UBXN7 | c.1009G>T p.E337* | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | catalogued as COSV99581735; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3620G>A p.R1207Q | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.182); catalogued as rs771147002, COSV54435806, COSV99692138; called by muse, mutect2, varscan2
- USP34 | c.3937G>C p.G1313R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101277207; called by muse, mutect2, varscan2
- YBX3 | c.322A>C p.N108H | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV54384444; called by muse, mutect2
- ZBTB21 | c.547A>G p.K183E | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.132); catalogued as rs1238737067, COSV100177359; called by muse, mutect2, varscan2
- ZC3H11A | c.2330T>C p.I777T | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs758595160, COSV100142768; called by muse, mutect2, varscan2
- ZFYVE16 | c.3550C>G p.P1184A | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100566638; called by muse, mutect2, varscan2
- ZKSCAN5 | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV100460373; called by muse, mutect2, varscan2
- ZMYM3 | c.1403A>C p.E468A | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100078382; called by muse, mutect2, varscan2
- ZMYM3 | c.514T>C p.S172P | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100078384; called by muse, mutect2, varscan2
- ZNF292 | c.6440C>A p.S2147* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV100371244; called by muse, mutect2, varscan2
- ZNF614 | c.1252C>T p.Q418* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV54545807; called by muse, mutect2
- ZNF682 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV100653354; called by muse, mutect2
- ZNF682 | c.88A>G p.R30G | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100653355; called by muse, mutect2, varscan2
- ADGRV1 | c.5510_5519del p.T1837Nfs*5 | Frame Shift Del (DEL) | VAF 35/113 reads (31%) | called by mutect2, pindel, varscan2
- ASTN2 | c.1319_1342del p.I440_A448delinsT (on ENST00000313400 / NM_001365069.1; = p.I389_A397delinsT on NM_014010.5) | In Frame Del (DEL) | VAF 26/44 reads (59%) | called by mutect2, pindel
- HCFC1 | c.1169_1201del p.A390_Y400del | In Frame Del (DEL) | VAF 22/122 reads (18%) | called by mutect2, pindel
- PLEKHH2 | c.4159-27_4165del p.X1387_splice | Splice Site (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel
- RBBP5 | c.1237del p.E413Kfs*15 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- ABCC2 | c.3541C>A p.R1181= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100966706, COSV64985861; called by muse, mutect2, varscan2
- ABCC9 | c.2532T>A p.I844= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99687191; called by muse, mutect2, varscan2
- ADAMDEC1 | c.429T>C p.C143= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV99836317; called by muse, mutect2, varscan2
- ANKAR | c.2640G>T p.V880= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99854632; called by muse, mutect2, varscan2
- ASTN1 | c.321C>A p.R107= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV56092456, COSV99923032; called by muse, mutect2, varscan2
- BCAS1 | c.1122C>G p.G374= | Silent (SNP) | VAF 9/148 reads (6%) | catalogued as COSV101006442; called by muse, mutect2
- CCR4 | c.1005C>G p.L335= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100447520; called by muse, mutect2, varscan2
- COL3A1 | c.1431G>A p.G477= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs368765585; ClinVar: likely benign; called by muse, mutect2
- DCAF1 | c.2940C>T p.D980= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100244941; called by muse, mutect2
- DHX37 | c.3468C>A p.V1156= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs531807352, COSV100439491; called by muse, mutect2, varscan2
- DUSP15 | c.93C>T p.I31= (on ENST00000278979 / NM_001320479.1; = p.I34= on NM_080611.4) | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as rs868354823, COSV99640206; called by muse, mutect2
- FLRT2 | c.1287C>T p.I429= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV100421006; called by muse, mutect2, varscan2
- GRIP1 | c.2298C>T p.F766= (on ENST00000359742 / NM_001379345.1; = p.F714= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs944380005, COSV99670969; called by muse, mutect2, varscan2
- GYG1 | c.954G>A p.S318= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs770605891, COSV56049301, COSV99936960; called by muse, mutect2, varscan2
- HENMT1 | c.1170G>A p.Q390= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100898687; called by muse, mutect2
- HMGCLL1 | c.813A>C p.P271= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV99233190; called by muse, mutect2, varscan2
- INO80 | c.1611T>C p.I537= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs1322280651, COSV100732065; called by muse, mutect2
- IRX5 | c.312G>A p.A104= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100315969; called by muse, mutect2
- KIAA1109 | c.11991A>G p.P3997= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs765614226, COSV99175560; called by mutect2, varscan2
- MAP3K13 | c.2385C>T p.L795= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as rs549099346, COSV99407940; called by muse, mutect2, varscan2
- MMP13 | c.402C>G p.V134= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV52824648, COSV99506857; called by muse, mutect2, varscan2
- OR4C12 | c.114A>T p.S38= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV100078681; called by muse, mutect2, varscan2
- OR5D18 | c.105C>A p.I35= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as COSV100450894, COSV61736069; called by muse, mutect2
- OR8G2P | c.657C>A p.I219= | Silent (SNP) | VAF 12/173 reads (7%) | called by muse, mutect2
- PCDHGA11 | c.813C>T p.D271= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1045003805, COSV53964452; called by muse, mutect2, varscan2
- PLOD1 | c.1641G>A p.L547= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV99538992; called by muse, mutect2, varscan2
- PTPRC | c.1668T>C p.F556= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100723168; called by muse, mutect2
- SLC26A4 | c.1752G>A p.A584= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs771015634, COSV55914542; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLITRK3 | c.2601T>A p.G867= | Silent (SNP) | VAF 41/82 reads (50%) | catalogued as COSV99580153; called by muse, mutect2, varscan2
- SPART | c.900A>G p.L300= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV62085119; called by muse, mutect2, varscan2
- TRIO | c.6717A>T p.T2239= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as rs1226202679, COSV100702715; called by muse, mutect2, varscan2
- VIRMA | c.1851A>T p.S617= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV52588651; called by muse, mutect2, varscan2
- ZFP69 | c.999G>A p.G333= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV101018385, COSV65529694; called by muse, mutect2, varscan2
- ANKRD13D | c.*621del | 3'UTR (DEL) | VAF 10/25 reads (40%) | catalogued as COSV57750609; called by mutect2, pindel, varscan2
- ARNT2 | c.*3523C>T | 3'UTR (SNP) | VAF 5/37 reads (14%) | catalogued as rs764320581, COSV57592247; called by muse, mutect2, varscan2
- PSG5 | c.431-2942C>T | Intron (SNP) | VAF 47/154 reads (31%) | catalogued as rs1383591244, COSV100743153; called by muse, mutect2, varscan2
- TTN | c.10360+5311G>T | Intron (SNP) | VAF 18/54 reads (33%) | catalogued as COSV100629454; called by muse, mutect2, varscan2
